Gene-level copy-number profile of tumor specimen TCGA-VR-AA7B-01A from TCGA case TCGA-VR-AA7B, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.5 years (23,915 days).
Specimen TCGA-VR-AA7B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.24a24d78-106b-4a43-92db-fc07a0468154.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-AA7B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1b8c6f3-0e76-4f34-9e08-21c072372799

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 170; copy number 1: 1,075; copy number 2: 13,086; copy number 3: 20,317; copy number 4: 16,188; copy number 5: 3,544; copy number 6: 1,625; copy number 7: 2,479; copy number 8: 111; copy number 9: 460; copy number 10: 38; copy number 11: 56; copy number 12: 193; copy number 13: 114; copy number 15: 127; copy number 19: 151; copy number 24: 57; copy number 41: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-AA7B-01A-31D-A402-01): tumor purity 0.59, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:212,426,263–212,426,360, 1 gene: MIR548F2.
- chr7:33,109,557–33,877,180, 1 gene (within-gene range 0–4): BBS9.
- chr7:33,177,740–33,732,064, 5 genes: RNA5SP229, AC007312.1, AC006195.1, AC008080.1, AC008080.2.
- chr9:14,475–3,691,814, 51 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:14,395,791–14,722,733, 7 genes: AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1.
- chr9:20,999,509–22,214,672, 55 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,605 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7–12 (broad region; genes not listed).
- chr4:53,377,839–54,295,272, 1 gene, copy number 7 (within-gene range 4–11): AC058822.1.
- chr4:53,592,956–54,102,498, 12 genes, copy number 7–11: LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2.
- chr4:58,524,515–58,565,212, 2 genes, copy number 7: LINC02494, AC019133.1.
- chr4:72,280,969–77,150,437, 103 genes, copy number 11–19 (broad region; genes not listed).
- chr4:77,216,416–77,216,878, 1 gene, copy number 12: AC008638.3.
- chr4:176,631,392–176,792,922, 3 genes, copy number 7: AC093801.2, AC093801.1, VEGFC.
- chr4:176,866,614–176,908,031, 2 genes, copy number 7: AC092673.1, LINC02509.
- chr7:103,099,776–118,951,259, 213 genes, copy number 7–13 (broad region; genes not listed).
- chr8:46,028,804–55,081,909, 135 genes, copy number 7 (broad region; genes not listed).
- chr8:79,520,145–80,543,104, 28 genes, copy number 9: AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4.
- chr8:82,033,533–82,961,926, 1 gene, copy number 9 (within-gene range 6–9): AC060765.2.
- chr8:82,514,568–94,707,466, 171 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:109,240,919–109,691,791, 8 genes, copy number 8: NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1.
- chr8:110,766,863–138,497,261, 317 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:19,401,872–19,401,981, 1 gene, copy number 8: RNA5SP335.
- chr11:68,261,338–75,206,549, 233 genes, copy number 15–24 (within-gene range 6–24) (broad region; genes not listed).
- chr11:76,860,867–79,989,630, 56 genes, copy number 7: ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr11:83,455,012–85,627,922, 1 gene, copy number 7 (within-gene range 6–7): DLG2.
- chr11:84,545,131–94,114,208, 212 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:65,278,643–74,402,600, 153 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr17:39,566,915–40,017,813, 24 genes, copy number 41: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3.
- chr19:21,225,098–21,427,577, 10 genes, copy number 9 (within-gene range 3–9): AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493.
- chr20:43,304,555–44,752,313, 47 genes, copy number 7: AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1.
- chr21:30,880,644–33,588,706, 69 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
